Gene-level copy-number profile of tumor specimen TCGA-12-0619-01A from TCGA case TCGA-12-0619, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.0 years (21,920 days).
Specimen TCGA-12-0619-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.f441d306-880e-4de6-9b83-6286307192f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0619-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30cc06cc-ea7c-4d2c-80f8-1917d8786397

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 2: 6,651; copy number 3: 18,558; copy number 4: 20,145; copy number 5: 11,015; copy number 6: 3,098; copy number 7: 62; copy number 8: 4; copy number 9: 195; copy number 11: 6; copy number 12: 3; copy number 13: 10; copy number 39: 35; copy number 69: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0619-01A-01D-0310-01): tumor purity 0.79, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:88,724,544–88,787,061, 4 genes: LIPK, KRT8P38, LIPN, RCBTB2P1.
- chr10:88,819,896–88,991,339, 5 genes (within-gene range 0–2): ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2.
- chr10:89,063,335–89,063,411, 2 genes: MIR4679-2, MIR4679-1.
- chr10:89,644,603–89,701,274, 4 genes (within-gene range 0–2): AL157400.5, AL157400.2, AL157400.1, AL157400.3.
- chr10:107,694,973–108,561,815, 3 genes (within-gene range 0–2): LINC01435, PTGES3P5, AL353740.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 264 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,564,855–155,331,114, 50 genes, copy number 9 (within-gene range 5–9): AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1, KCNN3, PMVK, AL451085.1, PBXIP1, Metazoa_SRP, PYGO2, AL451085.2, SHC1, CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1.
- chr2:14,530,941–16,855,284, 35 genes, copy number 39: Metazoa_SRP, AC011897.1, LRATD1, AC068286.2, AC068286.1, NBAS, RPS26P18, AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1.
- chr2:70,089,721–71,435,069, 48 genes, copy number 9 (within-gene range 4–9): AC016700.1, MRPL36P1, LINC01816, C2orf42, TIA1, MIR1285-2, RPL39P15, PCYOX1, SNRPG, FAM136A, AC022201.2, BRD7P6, AC022201.1, TGFA, TGFA-IT1, ADD2, AC005234.2, AC005234.1, FIGLA, HMGN2P21, CLEC4F, MOB4P1, CD207, LINC01143, AC007040.3, VAX2, ATP6V1B1, AC007040.2, ATP6V1B1-AS1, ELOCP21, RN7SL160P, ANKRD53, TEX261, AC007040.1, AC007881.2, OR7E91P, OR7E46P, OR7E62P, NAGK, AC007881.3, MCEE, AC007881.4, MPHOSPH10, AC007881.1, PAIP2B, ZNF638, AC007878.1, RNU6-105P.
- chr2:88,067,825–88,452,693, 10 genes, copy number 9 (within-gene range 4–9): SMYD1, MIR4780, FABP1, THNSL2, MRPL45P1, U6, RNU6-1168P, RNU6-1007P, RPL38P6, FOXI3.
- chr2:99,545,419–100,251,484, 3 genes, copy number 9 (within-gene range 4–9): AFF3, AC092667.1, LINC01104.
- chr2:105,744,912–105,962,386, 3 genes, copy number 12 (within-gene range 4–12): NCK2, AC010978.1, AC009505.1.
- chr3:113,746,872–113,947,570, 7 genes, copy number 13: AC108693.2, ATP6V1A, GRAMD1C, AC079944.1, AC079944.2, VPS26AP1, AC128687.2.
- chr3:138,187,248–139,006,268, 17 genes, copy number 9 (within-gene range 5–9): ARMC8, NME9, MRAS, ESYT3, AC022497.1, CEP70, FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A.
- chr3:139,019,031–139,125,171, 4 genes, copy number 9: PRR23B, PRR23C, RPL7L1P7, BPESC1.
- chr3:141,876,124–143,131,893, 32 genes, copy number 9 (within-gene range 5–9): ATP1B3, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1, RNU7-47P, PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1.
- chr3:148,991,408–149,752,495, 26 genes, copy number 9: GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2.
- chr3:149,779,009–149,779,108, 1 gene, copy number 9: RNU6-507P.
- chr3:181,372,732–181,700,611, 4 genes, copy number 9 (within-gene range 5–9): AC068308.1, RPL7AP25, AC125613.1, AC125613.2.
- chr3:183,548,735–183,812,624, 5 genes, copy number 11: KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1.
- chr3:183,815,922–183,825,594, 1 gene, copy number 11: MAP6D1.
- chr3:192,029,880–192,119,864, 3 genes, copy number 13: AC026320.1, AC026320.3, RN7SKP222.
- chr7:54,542,325–55,260,256, 15 genes, copy number 69: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
